Somatic mutation profile of tumor specimen TCGA-B5-A0KB-01B (aliquot TCGA-B5-A0KB-01B-11D-A14G-09) from TCGA case TCGA-B5-A0KB, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 62.1 years (22,669 days).
Specimen TCGA-B5-A0KB-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f012c521-70db-4db0-8891-02c9799a2d39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0KB-10A (Blood Derived Normal), aliquot TCGA-B5-A0KB-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b5c39d0-b4e1-4b14-ae23-81af92d2927e

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 12, Nonsense Mutation 3, Splice Site 1, Frame Shift Del 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.1549A>G p.I517V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1433459805, COSV100741777; called by muse, mutect2, varscan2
- ACBD5 | c.1022C>A p.S341Y (on ENST00000375888 / NM_001352568.1; = p.S332Y on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as COSV101022540; called by muse, mutect2, varscan2
- ARHGEF5 | c.4744G>C p.A1582P | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99282812; called by muse, mutect2, varscan2
- CDH8 | c.2310C>G p.D770E | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.823); catalogued as COSV100181435, COSV100182477; called by muse, mutect2, varscan2
- CSMD1 | c.5447C>A p.S1816Y (on ENST00000520002; = p.S1815Y on NM_033225.6) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs988360775, COSV59386524; called by muse, mutect2, varscan2
- DSCAM | c.1342C>A p.L448I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV101260069; called by muse, mutect2, varscan2
- ERRFI1 | c.752C>A p.S251* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV101088096; called by muse, mutect2, varscan2
- FMO5 | c.1027G>C p.V343L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV54207442, COSV99567015; called by muse, mutect2, varscan2
- FOXD4L5 | c.993C>G p.C331W | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.869); catalogued as rs1446797224; called by mutect2, varscan2
- FUT3 | c.948C>G p.Y316* | Nonsense Mutation (SNP) | VAF 49/103 reads (48%) | catalogued as COSV54605601, COSV99744567; called by muse, mutect2, varscan2
- IGSF9 | c.2443C>G p.R815G (on ENST00000368094 / NM_001135050.2; = p.R799G on NM_020789.4) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV100231136; called by muse, mutect2, varscan2
- IGSF9B | c.1400C>A p.A467D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV100317579; called by muse, mutect2, varscan2
- INPP5B | c.325G>C p.V109L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100886171; called by muse, mutect2, varscan2
- MAP1A | c.329A>G p.E110G | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100288639; called by muse, mutect2, varscan2
- MERTK | c.2251G>T p.G751C | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99774612; called by muse, mutect2
- MTA2 | c.925A>T p.M309L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as COSV99545290; called by muse, mutect2, varscan2
- MYH3 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs935061024, COSV99878196; called by muse, mutect2, varscan2
- OR14C36 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.089); catalogued as rs776779347, COSV100507658, COSV58602490; called by muse, mutect2, varscan2
- OR2M5 | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.983); catalogued as COSV63546401; called by muse, mutect2, varscan2
- PROKR2 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs142008002, CM1410088; called by muse, mutect2, varscan2
- PTPRK | c.1342A>G p.K448E | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.424); catalogued as COSV100951027; called by muse, mutect2
- PYHIN1 | c.572C>G p.S191* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as COSV100932350, COSV100932403, COSV63721376; called by muse, mutect2
- SIGLEC12 | c.1210G>A p.D404N (on ENST00000291707 / NM_053003.4; = p.D286N on NM_033329.2) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.55); catalogued as rs28676678; called by muse, mutect2, varscan2
- SLC2A4RG | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777497511, COSV99829139, COSV99829157; called by muse, varscan2
- SLITRK3 | c.178C>A p.H60N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.954); catalogued as COSV53853830, COSV99579209; called by muse, mutect2, varscan2
- SYDE2 | c.2848G>C p.E950Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV58325290; called by muse, mutect2
- TNFRSF1B | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs764464033, COSV100884155; called by muse, mutect2, varscan2
- UBR4 | c.8310+1G>A p.X2770_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100920755; called by muse, mutect2, varscan2
- ZMYND8 | c.2273C>T p.P758L (on ENST00000311275 / NM_001363741.2; = p.P778L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as rs780491504, COSV53684289; called by muse, mutect2, varscan2
- SLC25A3 | c.91_94del p.S31Afs*55 (on ENST00000228318 / NM_005888.3; = p.S31Afs*42 on NM_002635.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | called by mutect2, pindel, varscan2
- ACR | c.459G>A p.S153= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs768599127, COSV99334425; called by muse, mutect2, varscan2
- CARS1 | c.1908C>A p.P636= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99542694; called by muse, mutect2
- CSMD1 | c.5448C>A p.S1816= (on ENST00000520002; = p.S1815= on NM_033225.6) | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100147568; called by muse, mutect2
- FARP2 | c.1884C>G p.R628= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99884596; called by muse, mutect2, varscan2
- HSPA12B | c.579A>T p.P193= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99653990; called by muse, mutect2, varscan2
- IL13RA2 | c.672A>G p.R224= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99683053; called by muse, mutect2, varscan2
- MC5R | c.660G>A p.A220= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs776746415, COSV100229030; called by mutect2, varscan2
- MRPS27 | c.27G>T p.G9= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1397961281, COSV99782195; called by muse, mutect2, varscan2
- P2RY2 | c.273T>C p.Y91= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100232729; called by muse, mutect2, varscan2
- USH2A | c.14349C>T p.S4783= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs770927582, COSV100229776, COSV56332969; ClinVar: likely benign; called by muse, mutect2, varscan2
- VMP1 | c.309G>A p.V103= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99230388; called by muse, mutect2, varscan2
- ZFPM2 | c.2526G>T p.R842= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV101023213; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847071 G>A | 5'Flank (SNP) | VAF 4/24 reads (17%) | catalogued as rs775057261; called by muse, mutect2, varscan2
- PLCB1 | c.594+1969A>G | Intron (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
